Somatic mutation profile of tumor specimen TCGA-CN-A641-01A (aliquot TCGA-CN-A641-01A-11D-A30E-08) from TCGA case TCGA-CN-A641, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.8 years (17,454 days).
Specimen TCGA-CN-A641-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc643554-6087-4dcc-a8f3-3a697e059b68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A641-10A (Blood Derived Normal), aliquot TCGA-CN-A641-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104b2bf4-725a-4e71-8c01-d5e1b47bb74e

The open-access MAF lists 233 somatic variants for this specimen: 175 protein-altering or splice-affecting, 54 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 54, Nonsense Mutation 7, Splice Site 4, Frame Shift Del 4, Frame Shift Ins 4, RNA 2, Splice Region 1, 3'Flank 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 21/35 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2418C>G p.C806W | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV99286978; called by muse, mutect2, varscan2
- ABCB5 | c.2675G>T p.R892M (on ENST00000404938 / NM_001163941.2; = p.R447M on NM_178559.6) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV51706695, COSV99329770; called by muse, mutect2, varscan2
- AFF4 | c.2308-2A>G p.X770_splice | Splice Site (SNP) | VAF 101/285 reads (35%) | catalogued as COSV99535429; called by muse, mutect2, varscan2
- AK5 | c.1344G>T p.M448I (on ENST00000354567 / NM_174858.3; = p.M422I on NM_012093.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV100643417; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2704A>T p.I902F | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV99784544; called by muse, mutect2, varscan2
- ANKRD10 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs760264983, COSV57442558; called by muse, mutect2, varscan2
- ANKRD26 | c.1539G>A p.M513I | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs565311134, COSV65796397; called by muse, mutect2, varscan2
- ASB15 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99306421, COSV99307011; called by muse, mutect2, varscan2
- ASH1L | c.8467G>T p.D2823Y (on ENST00000368346 / NM_001366177.2; = p.D2818Y on NM_018489.3) | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100853608; called by muse, mutect2, varscan2
- ATP10A | c.3791C>A p.T1264N | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100791556; called by muse, mutect2, varscan2
- AZGP1 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99448223, COSV99448237; called by muse, mutect2, varscan2
- BEST2 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 148/220 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50361444, COSV99244684; called by muse, mutect2, varscan2
- BOD1L1 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50015843, COSV99240474; called by muse, mutect2, varscan2
- C1orf105 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV99278410; called by muse, mutect2, varscan2
- CATSPER1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1033780625, COSV100375988, COSV56412522; called by muse, mutect2, varscan2
- CCNL2 | c.658T>C p.W220R | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101275735; called by muse, mutect2, varscan2
- CDH10 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52584561, COSV52585895; called by muse, mutect2, varscan2
- CDK8 | c.570G>T p.L190F | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101037656; called by muse, mutect2, varscan2
- CFAP54 | c.6136T>C p.Y2046H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100733361; called by muse, mutect2, varscan2
- CFAP54 | c.6799C>G p.L2267V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV100733362; called by muse, mutect2, varscan2
- CHRNA3 | c.1229T>A p.I410K | Missense Mutation (SNP) | VAF 99/168 reads (59%) | SIFT tolerated (0.9); PolyPhen benign (0.079); catalogued as COSV100467914; called by muse, mutect2, varscan2
- CILP | c.3343C>T p.L1115F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99973965; called by muse, mutect2, varscan2
- CNTN1 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.056); catalogued as rs757618456, COSV100751924; called by muse, mutect2, varscan2
- COL11A1 | c.486del p.K163Sfs*5 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as COSV62183926; called by mutect2, pindel, varscan2
- COL19A1 | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100507577; called by muse, mutect2, varscan2
- CRP | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs769752475, COSV99660768; called by muse, mutect2, varscan2
- CSMD1 | c.9151G>A p.G3051R (on ENST00000520002; = p.G3050R on NM_033225.6) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59394539; called by muse, mutect2, varscan2
- CSMD2 | c.5194G>A p.A1732T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.916); catalogued as COSV99595680; called by muse, mutect2, varscan2
- CSMD3 | c.8583C>A p.H2861Q (on ENST00000297405 / NM_001363185.1; = p.H2692Q on NM_052900.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99848549; called by muse, mutect2, varscan2
- CTC1 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1010062693, COSV59852425; called by muse, mutect2, varscan2
- DBH | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV99708144; called by muse, mutect2, varscan2
- DCAF12L2 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 80/115 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV63581024; called by muse, mutect2, varscan2
- DDX20 | c.1081A>T p.R361* | Nonsense Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as COSV100865968; called by muse, mutect2, varscan2
- DENND4C | c.4420G>A p.E1474K (on ENST00000434457 / NM_001330640.2; = p.E1425K on NM_017925.7) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.823); catalogued as COSV100727605; called by muse, mutect2
- DHX36 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100273979; called by muse, mutect2, varscan2
- DMRT3 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as rs554739680, COSV99506093; called by muse, mutect2, varscan2
- DNAH7 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100417692; called by muse, mutect2, varscan2
- DPYD | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100929465; called by muse, mutect2, varscan2
- EGFLAM | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100473619; called by muse, mutect2, varscan2
- ELMO1 | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100166182, COSV60302454; called by muse, mutect2, varscan2
- EPHA6 | c.2284G>T p.G762C (on ENST00000389672 / NM_001080448.3; = p.G154C on NM_173655.4) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101065698; called by muse, mutect2, varscan2
- ERC1 | c.2900G>A p.R967H (on ENST00000360905 / NM_178040.4; = p.R939H on NM_178039.4) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs772856192, COSV61697884; called by muse, mutect2, varscan2
- F13B | c.1093A>T p.K365* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100803465; called by muse, varscan2
- F9 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99496909; called by muse, mutect2, varscan2
- FAM114A2 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100697806; called by muse, mutect2, varscan2
- FAM135B | c.250A>C p.N84H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs774016466, COSV99358264; called by muse, mutect2, varscan2
- FAM189A2 | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99975397; called by muse, mutect2, varscan2
- FAM3D | c.46A>G p.I16V | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1193052565, COSV100717029; called by muse, mutect2, varscan2
- FAM47A | c.652A>C p.T218P | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV100650098, COSV60498594; called by muse, mutect2, varscan2
- FAT3 | c.4237G>C p.G1413R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99971332; called by muse, mutect2, varscan2
- FBN1 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100356463; called by muse, mutect2, varscan2
- FDX2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99533166; called by muse, mutect2, varscan2
- FOXD4L3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1226826559; called by mutect2, varscan2
- GABRA1 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99196292; called by muse, mutect2, varscan2
- GABRA1 | c.322A>C p.M108L | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV50106803, COSV99196293; called by muse, mutect2, varscan2
- GIP | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100656965, COSV62467056, COSV62467669; called by muse, mutect2, varscan2
- H2BC5 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV56800630, COSV56801968; called by muse, mutect2
- HAVCR1 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV100208200, COSV100208612; called by muse, mutect2, varscan2
- HELZ2 | c.448A>T p.S150C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100915716; called by muse, varscan2
- HERC2 | c.6685G>T p.G2229* | Nonsense Mutation (SNP) | VAF 29/56 reads (52%) | catalogued as COSV55338659, COSV99876854; called by muse, mutect2, varscan2
- HMCN1 | c.7778C>T p.T2593I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.998); catalogued as rs1013128897, COSV99636169; called by muse, mutect2, varscan2
- ICAM5 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 98/1079 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV99703537; called by muse, mutect2
- IGKV1D-43 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs769578195; called by muse, mutect2, varscan2
- IL5RA | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99843338; called by muse, mutect2, varscan2
- ITGAL | c.2884C>A p.H962N | Missense Mutation (SNP) | VAF 50/476 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.585); catalogued as rs748618358, COSV100776360; called by muse, mutect2, varscan2
- JADE1 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99886321; called by muse, mutect2, varscan2
- KCNA3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV63902597; called by muse, mutect2, varscan2
- KDM4B | c.2437A>G p.R813G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99347504; called by muse, mutect2, varscan2
- KIF14 | c.3125A>G p.D1042G | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100951094; called by muse, mutect2, varscan2
- KRBA2 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100497728; called by muse, mutect2, varscan2
- LDLRAD1 | c.21+1G>A p.X7_splice | Splice Site (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100744538; called by muse, mutect2, varscan2
- LMO4 | c.128G>C p.W43S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100984006; called by muse, mutect2, varscan2
- LRMDA | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV100995431; called by muse, mutect2, varscan2
- LRRC40 | c.1329G>A p.R443= | Splice Region (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100918861, COSV100918878; called by muse, mutect2, varscan2
- LRRC4C | c.196A>T p.N66Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99539881; called by muse, mutect2, varscan2
- MACF1 | c.16259G>A p.R5420K (on ENST00000372915; = p.R3353K on NM_012090.5) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as COSV99246987; called by muse, mutect2, varscan2
- MAP3K7 | c.899A>G p.Y300C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100997567; called by muse, mutect2, varscan2
- MEGF6 | c.4407T>G p.F1469L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV99621413; called by muse, mutect2, varscan2
- MKRN2 | c.769G>C p.G257R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV99403436; called by muse, mutect2, varscan2
- MORC2 | c.2898G>C p.Q966H (on ENST00000397641 / NM_001303256.3; = p.Q904H on NM_014941.3) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV99310460; called by muse, mutect2, varscan2
- MRGPRX3 | c.516G>C p.W172C | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV101283585; called by muse, mutect2, varscan2
- MYH13 | c.5556G>T p.K1852N | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52834672; called by muse, mutect2, varscan2
- MYH2 | c.1081C>A p.H361N | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99821011; called by muse, mutect2, varscan2
- MYH6 | c.853C>A p.H285N | Missense Mutation (SNP) | VAF 99/337 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100677022; called by muse, mutect2, varscan2
- MYOC | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99231742, COSV99231782; called by muse, mutect2, varscan2
- NAALADL2 | c.1586G>A p.S529N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV101380516; called by muse, mutect2, varscan2
- NCKAP5 | c.1867T>G p.F623V | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.053); catalogued as COSV100494513; called by muse, mutect2, varscan2
- NCOR2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs757613317, COSV62294070, COSV62295460; called by muse, mutect2, varscan2
- NHLRC1 | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100513565; called by muse, mutect2, varscan2
- NIM1K | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV100390511; called by muse, mutect2, varscan2
- NIN | c.5852T>A p.V1951E (on ENST00000382041 / NM_182946.1; = p.V1238E on NM_016350.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99815386; called by muse, mutect2, varscan2
- NME7 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100891204; called by muse, mutect2, varscan2
- NSD1 | c.5690G>T p.C1897F | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729826; called by muse, mutect2, varscan2
- NSD1 | c.5842C>A p.R1948S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CM1211952, COSV61773891; called by muse, varscan2
- NSD1 | c.5843G>T p.R1948L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100729659; called by muse, varscan2
- NYAP2 | c.1346T>G p.L449R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99798649; called by muse, mutect2, varscan2
- OR4M1 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV100271525; called by muse, mutect2, varscan2
- OR51G2 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV100432244; called by muse, mutect2, varscan2
- OR52I1 | c.299C>G p.A100G | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.917); catalogued as COSV100331832, COSV56169453; called by muse, mutect2, varscan2
- OR5AK2 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.06); catalogued as COSV100476169; called by muse, mutect2, varscan2
- OR5H15 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV100736772; called by muse, mutect2, varscan2
- OR6B2 | c.107T>A p.L36H | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99401768; called by muse, mutect2, varscan2
- OR6K2 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV100656891; called by muse, mutect2, varscan2
- OR6N2 | c.660G>T p.R220S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.339); catalogued as COSV100210512, COSV100210578; called by muse, mutect2, varscan2
- OR8H3 | c.213C>A p.D71E | Missense Mutation (SNP) | VAF 109/506 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs529741757, COSV100539157; called by muse, mutect2, varscan2
- OR8U1 | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.155); catalogued as COSV100164140; called by muse, varscan2
- OTOL1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 12/146 reads (8%) | catalogued as COSV100020278; called by muse, mutect2
- OTUD7B | c.2389C>G p.P797A | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV100967801; called by muse, mutect2, varscan2
- PCDH10 | c.2073C>A p.S691R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as COSV99994584; called by muse, varscan2
- PCDH8 | c.2861A>T p.E954V | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100132068; called by muse, mutect2, varscan2
- PCDHA11 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); catalogued as rs1554163605, COSV100254762; called by muse, mutect2, varscan2
- PGBD2 | c.58T>A p.S20T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV100252259; called by muse, mutect2, varscan2
- PIEZO2 | c.7973G>T p.S2658I | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99555562; called by muse, mutect2, varscan2
- PKHD1L1 | c.3829G>A p.V1277I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.194); catalogued as rs772722585, COSV101006868; called by muse, mutect2, varscan2
- PLA2G4E | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV101268647; called by muse, mutect2, varscan2
- PLCE1 | c.3001G>T p.G1001* | Nonsense Mutation (SNP) | VAF 45/138 reads (33%) | catalogued as COSV53355442; called by muse, mutect2, varscan2
- PRAMEF12 | c.383G>T p.S128I | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV100743603; called by muse, mutect2, varscan2
- PRB1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.703); catalogued as COSV99555966; called by muse, mutect2, varscan2
- PRDM9 | c.551G>C p.R184P | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779766814, COSV57012958, COSV99689947, COSV99691313; called by muse, mutect2, varscan2
- PREX2 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55785612, COSV99910132; called by muse, mutect2, varscan2
- PRR35 | c.636C>G p.N212K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99552296; called by muse, mutect2
- PTPRB | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs764058489, COSV99318862; called by muse, mutect2, varscan2
- RALBP1 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as COSV99192041; called by muse, mutect2, varscan2
- RBX1 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV99345492; called by muse, mutect2, varscan2
- RGS18 | c.644G>C p.R215P | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100817909, COSV66507541; called by muse, mutect2, varscan2
- RHEB | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100062390; called by muse, mutect2, varscan2
- RTF2 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV99196560; called by muse, mutect2, varscan2
- SCP2 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV101027251; called by muse, mutect2, varscan2
- SEC61A1 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV99685046; called by muse, mutect2, varscan2
- SERPINA4 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.117); catalogued as COSV100097499; called by muse, mutect2, varscan2
- SH3TC2 | c.2261G>T p.S754I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as COSV100102381; called by muse, mutect2, varscan2
- SI | c.2867C>A p.T956K | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100017272; called by muse, mutect2, varscan2
- SLC13A3 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV51719459; called by muse, mutect2, varscan2
- SLC26A6 | c.281T>A p.L94Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99375061; called by muse, mutect2, varscan2
- SLC35C2 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99709602; called by muse, mutect2, varscan2
- SLC38A10 | c.2023G>A p.V675M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs561261394, COSV99917944; called by muse, varscan2
- SLC39A12 | c.2028G>T p.W676C (on ENST00000377369 / NM_001145195.2; = p.W639C on NM_152725.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101070184, COSV104426486; called by muse, mutect2, varscan2
- SLC47A1 | c.136-1G>A p.X46_splice | Splice Site (SNP) | VAF 35/92 reads (38%) | catalogued as COSV99565658; called by muse, mutect2, varscan2
- SLC6A1 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99823254; called by muse, mutect2, varscan2
- SP140 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as rs778848255, COSV100614109; called by muse, mutect2, varscan2
- ST8SIA3 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | PolyPhen probably damaging (0.977); catalogued as rs267605214, COSV60654522; called by muse, mutect2, varscan2
- TBC1D12 | c.1373T>C p.V458A | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV99831830; called by muse, mutect2, varscan2
- TEAD4 | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100622188; called by muse, mutect2, varscan2
- TLE1 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100916026; called by muse, mutect2, varscan2
- TMEM132D | c.115A>G p.R39G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV101396554, COSV70594836; called by muse, mutect2, varscan2
- TMEM202 | c.470T>G p.M157R | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100499272; called by muse, mutect2, varscan2
- TNN | c.2873G>T p.G958V | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380887038, COSV53421591; called by muse, mutect2, varscan2
- TNS3 | c.1326G>T p.K442N | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as COSV100236497; called by muse, mutect2, varscan2
- TRPM2 | c.3520G>T p.E1174* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs1386238761, COSV100309349; called by muse, mutect2, varscan2
- TRPM3 | c.4205C>T p.S1402L (on ENST00000357533 / NM_001366142.2; = p.S1257L on NM_020952.6) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.728); catalogued as rs1477490960, COSV62584230; called by muse, mutect2, varscan2
- TSBP1 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 127/237 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100898948; called by muse, mutect2, varscan2
- TSPOAP1 | c.1420C>A p.Q474K | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV99272823; called by muse, mutect2, varscan2
- TTC30B | c.1913G>C p.R638T | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.045); catalogued as COSV101282812; called by muse, mutect2, varscan2
- TTN | c.93679T>G p.F31227V (on ENST00000591111; = p.F23803V on NM_003319.4) | Missense Mutation (SNP) | VAF 45/131 reads (34%) | PolyPhen probably damaging (0.996); catalogued as COSV100631068; called by muse, mutect2, varscan2
- TTN | c.77099G>T p.R25700L (on ENST00000591111; = p.R18276L on NM_003319.4) | Missense Mutation (SNP) | VAF 72/240 reads (30%) | PolyPhen probably damaging (0.998); catalogued as COSV100631070; called by muse, mutect2, varscan2
- TYR | c.815G>T p.W272L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779454147, COSV99635400; called by muse, mutect2, varscan2
- WIPF3 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.109); catalogued as rs752160943, COSV54208185, COSV99635251; called by muse, varscan2
- ZBED9 | c.121C>A p.R41S | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV101509401; called by muse, mutect2
- ZBED9 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.326); catalogued as rs906782517, COSV101509402; called by muse, mutect2
- ZBP1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV100474004; called by muse, mutect2, varscan2
- ZFHX4 | c.9115G>T p.V3039F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51496808, COSV51500069, COSV99264351; called by muse, mutect2, varscan2
- ZNF112 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100496309; called by muse, mutect2, varscan2
- ZNF236 | c.2807G>T p.R936L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.253); catalogued as rs753917729, COSV99471284; called by muse, mutect2, varscan2
- ZNF521 | c.2828A>C p.N943T | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.066); catalogued as COSV100833467; called by muse, mutect2, varscan2
- ZNF567 | c.756dup p.H253Tfs*5 (on ENST00000536254 / NM_001322913.1; = p.H222Tfs*5 on NM_152603.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 8/19 reads (42%) | catalogued as rs762873548; called by mutect2, varscan2
- ZNF71 | c.443A>T p.H148L | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100046330; called by muse, mutect2, varscan2
- ADAMDEC1 | c.200del p.G67Afs*14 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- CA8 | c.290_292+14del p.X97_splice | Splice Site (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel
- CEP83 | c.424del p.E142Kfs*32 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, varscan2
- CP | c.13_19del p.I5Vfs*78 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- KCNV1 | c.1098dup p.A367Cfs*2 | Frame Shift Ins (INS) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- KPNA2 | c.1567dup p.A523Gfs*6 | Frame Shift Ins (INS) | VAF 33/204 reads (16%) | called by mutect2, pindel, varscan2
- NSD1 | c.5840dup p.R1948Pfs*16 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by pindel, varscan2
- TRAV8-1 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- ARHGAP31 | c.1428G>A p.S476= | Silent (SNP) | VAF 48/170 reads (28%) | catalogued as COSV99957767; called by muse, mutect2, varscan2
- ARHGAP32 | c.363G>T p.A121= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100089397, COSV59847289; called by muse, mutect2, varscan2
- ASPH | c.1869G>A p.G623= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV101064469; called by muse, mutect2, varscan2
- CEP83 | c.423A>C p.V141= | Silent (SNP) | VAF 22/84 reads (26%) | called by mutect2, varscan2
- CEP85L | c.2106C>G p.S702= | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as COSV100874382; called by muse, mutect2, varscan2
- CES5A | c.840C>T p.N280= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs145972420; called by muse, mutect2, varscan2
- CFHR5 | c.348A>T p.T116= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV99889793; called by muse, mutect2, varscan2
- CSMD3 | c.5832T>C p.T1944= (on ENST00000297405 / NM_001363185.1; = p.T1840= on NM_052900.3) | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99848550; called by muse, mutect2, varscan2
- CTNND2 | c.2982C>A p.S994= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100481269; called by muse, mutect2, varscan2
- DCAF4L1 | c.471G>A p.V157= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as COSV100296019; called by muse, mutect2, varscan2
- DSTN | c.94A>C p.R32= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV99855285; called by muse, mutect2, varscan2
- DYSF | c.1368C>T p.C456= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as rs202044973, CM053215, COSV50281885; called by muse, mutect2, varscan2
- EPB41L3 | c.2739C>A p.V913= | Silent (SNP) | VAF 44/185 reads (24%) | catalogued as COSV100550347; called by muse, mutect2, varscan2
- EPHB1 | c.1161G>A p.T387= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs367562212, COSV67665721; called by muse, mutect2, varscan2
- EPN3 | c.1344C>T p.S448= | Silent (SNP) | VAF 67/282 reads (24%) | catalogued as COSV99277446; called by muse, mutect2, varscan2
- GABRB2 | c.1023A>T p.A341= | Silent (SNP) | VAF 33/178 reads (19%) | catalogued as COSV99196692; called by muse, mutect2, varscan2
- GAP43 | c.339G>A p.K113= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100525968; called by muse, mutect2, varscan2
- GPR119 | c.646C>A p.R216= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV99358724; called by muse, mutect2, varscan2
- HSPA12A | c.315G>T p.L105= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV100979966; called by muse, mutect2, varscan2
- IGDCC3 | c.1554G>T p.L518= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100031539; called by muse, mutect2, varscan2
- IL2 | c.363A>C p.T121= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99900845; called by muse, mutect2, varscan2
- KANK4 | c.174C>T p.H58= | Silent (SNP) | VAF 78/231 reads (34%) | catalogued as COSV100587728; called by muse, mutect2, varscan2
- KCNB2 | c.1563C>T p.H521= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as rs779284283, COSV101579021; called by muse, mutect2, varscan2
- LBX1 | c.57G>A p.P19= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs753609321, COSV100929975; called by muse, mutect2, varscan2
- LRRC8B | c.2411G>A p.*804= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100446714; called by muse, mutect2, varscan2
- MAP2 | c.315C>T p.V105= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99561816; called by muse, mutect2, varscan2
- MCM3AP | c.1461T>C p.A487= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV99387547; called by muse, mutect2, varscan2
- MFN1 | c.552C>T p.V184= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV99764728; called by muse, mutect2, varscan2
- MYH1 | c.4578C>G p.R1526= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV56852006, COSV99876943; called by muse, mutect2, varscan2
- NRG3 | c.738C>A p.P246= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100932585; called by muse, mutect2, varscan2
- OR4C6 | c.732G>T p.V244= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV100051682; called by muse, mutect2, varscan2
- OR4K2 | c.444C>A p.S148= | Silent (SNP) | VAF 75/402 reads (19%) | catalogued as COSV53847901, COSV53850716; called by muse, mutect2, varscan2
- OR52N1 | c.627G>T p.G209= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100398735; called by muse, mutect2, varscan2
- ORAI1 | c.552G>T p.T184= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100345506, COSV57491885; called by muse, mutect2, varscan2
- PEX5L | c.750C>G p.R250= | Silent (SNP) | VAF 59/94 reads (63%) | catalogued as COSV99829991; called by muse, mutect2, varscan2
- PIDD1 | c.1110G>T p.L370= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs970748133, COSV100758795; called by muse, mutect2, varscan2
- PIK3C2G | c.1851G>T p.A617= (on ENST00000676171; = p.A576= on NM_004570.5) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99854113; called by muse, mutect2, varscan2
- PIWIL2 | c.750T>C p.N250= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs180791960, COSV100769553, COSV63252666; called by muse, mutect2, varscan2
- PNPLA7 | c.3444G>A p.T1148= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as COSV99481458; called by muse, mutect2, varscan2
- PPIH | c.276G>A p.R92= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs374293387; called by muse, mutect2, varscan2
- PRDM11 | c.1095C>T p.I365= (on ENST00000530656 / NM_001359633.1; = p.I331= on NM_001256695.1) | Silent (SNP) | VAF 85/252 reads (34%) | catalogued as COSV99771136; called by muse, mutect2, varscan2
- PSMC5 | c.495C>T p.I165= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as rs753804276, COSV56738557; called by muse, mutect2, varscan2
- PUM2 | c.3153G>T p.P1051= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as COSV100164019; called by muse, mutect2, varscan2
- PYROXD1 | c.792G>A p.K264= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV99556793; called by muse, mutect2, varscan2
- SEC16A | c.3582C>A p.L1194= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as rs1403942624, COSV99260259; called by muse, mutect2
- SLC24A2 | c.369C>T p.D123= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs749000225, COSV99647516; called by muse, mutect2, varscan2
- SNRNP200 | c.4293G>A p.K1431= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as rs781245650, COSV100108068; called by muse, mutect2, varscan2
- SPAG1 | c.2112C>G p.L704= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99309499; called by muse, mutect2, varscan2
- SPAG17 | c.2151T>C p.N717= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as COSV100310658; called by muse, mutect2, varscan2
- SPTA1 | c.6594A>C p.A2198= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100935616; called by muse, mutect2
- TCTE3 | c.537T>C p.A179= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV100825451; called by muse, mutect2, varscan2
- TTN | c.63003C>A p.G21001= (on ENST00000591111; = p.G13577= on NM_003319.4) | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100620227, COSV100631071; called by muse, mutect2, varscan2
- ZC2HC1A | c.87A>T p.V29= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as COSV99804339, COSV99804480; called by muse, mutect2, varscan2
- ZNF816 | c.501C>A p.L167= | Silent (SNP) | VAF 154/258 reads (60%) | catalogued as COSV99554721; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83164G>A | Intron (SNP) | VAF 139/431 reads (32%) | catalogued as rs374781409; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152447116 T>C | 3'Flank (SNP) | VAF 68/176 reads (39%) | called by mutect2, varscan2
- SSPOP | n.8887G>T | RNA (SNP) | VAF 28/56 reads (50%) | catalogued as COSV100946937, COSV65139374; called by muse, mutect2, varscan2
- UBTFL2 | n.610G>A | RNA (SNP) | VAF 11/44 reads (25%) | called by mutect2, varscan2
